Gene-level copy-number profile of tumor specimen TCGA-X6-A8C4-01A from TCGA case TCGA-X6-A8C4, project TCGA-SARC (Sarcoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Undifferentiated sarcoma; Tissue or organ of origin: Connective, subcutaneous and other soft tissues of lower limb and hip; Age at diagnosis: 70.9 years (25,896 days).
Specimen TCGA-X6-A8C4-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SARC.5c1df810-e043-40e8-88c3-8444210d3339.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-X6-A8C4-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 824 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5f148d79-4843-48c9-9895-7040a3d11cc7

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 65; copy number 1: 4,064; copy number 2: 18,305; copy number 3: 18,752; copy number 4: 12,119; copy number 5: 4,591; copy number 6: 1,422; copy number 7: 359; copy number 8: 86; copy number 10: 36.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-X6-A8C4-01A-11D-A36I-01): tumor purity 0.92, ploidy 3.03, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 54 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:13,274,510–13,323,450, 2 genes: AL162386.2, AL162386.1.
- chr9:13,406,380–13,488,125, 1 gene (within-gene range 0–4): LINC01235.
- chr9:15,553,043–16,061,663, 1 gene (within-gene range 0–4): CCDC171.
- chr9:15,776,181–17,503,923, 14 genes: RNU6-14P, C9orf92, BNC2, AL449983.1, AL450003.1, BNC2-AS1, LSM1P1, AL162725.2, AL358117.1, RN7SL720P, RPS29P33, AL162725.1, CNTLN, SAMM50P1.
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–4): MTAP, AL359922.1.
- chr9:21,892,188–21,995,301, 4 genes: AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–22,046,901, 4 genes: AL449423.1, CDKN2B, UBA52P6, AL354709.1.
- chr9:22,446,824–22,455,740, 1 gene: DMRTA1.
- chr9:25,676,389–26,118,408, 4 genes: TUSC1, LINC01241, FAM71BP1, AL353753.1.
- chr14:106,714,684–106,875,071, 21 genes: IGHV1-69, IGHV2-70D, IGHV3-69-1, IGHV1-69-2, AC245369.21, IGHV1-69D, IGHV2-70, IGHV3-71, IGHV3-72, IGHV3-73, IGHV3-74, IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV4-80, IGHV7-81.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 481 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr3:11,745–54,346, 2 genes, copy number 7: LINC01986, AC066595.1.
- chr3:123,563–133,500, 1 gene, copy number 7 (within-gene range 5–7): AC066595.2.
- chr4:34,657,606–34,714,598, 2 genes, copy number 8: AC093689.1, AC093913.1.
- chr5:1,931,058–28,287,807, 356 genes, copy number 7 (broad region; genes not listed).
- chr9:841,690–7,961,224, 120 genes, copy number 8–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,429. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
